Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A3MH, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A3MH-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Clinical Case Report (For Collection of Cancerous Tissue)

ICD-0-3

Carcinoma, papillary urothelial 8130/3

Site: bladder, nos C67.9

lw
1/2/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
		☐ Single ☒ Married		
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female			12/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Lower abdominal pain; fever.
Symptoms: Hematuria; weight loss.
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☒ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO		1 1/2 P / day	50 (yrs)	still smoke (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks / day	(yrs)	3 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____	9/	CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____	1/	CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound ☒		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0		Stage: II B

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Resection of total U Bladder		
Primary Tumor		
Organ	Detailed Location	Size
Urinary bladder	overlapping lesion of bladder	4.5 x 1 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 2	N 0	M 0
Stage:		II B

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____
Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
urinary bladder	1.5 x 1 x cm	overlapping	4 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2	N 0	M 0	Stage: II B
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION	+	-	STRUCTURAL PATTERN	+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis		X	Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized		X	Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	X		Glandular cell			Round Cell			Large Cell		
Spindle Cell	X		Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Otherwise Specified:

D. 70% Ad 60% P 35% A 0%

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				
Nuclear Grade				

Histological Diagnosis: *Papillary Transitional cell Carcinoma, G2*

Comments:

Date

Director, Research Pathology

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 11884bbe-2fa3-411f-ad54-7d64265cbe8f (TCGA-CF-A3MH.5C446B3A-D6FB-4301-97E9-D713F985FEBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).